Somatic mutation profile of tumor specimen TCGA-CZ-5465-01A (aliquot TCGA-CZ-5465-01A-01D-1806-10) from TCGA case TCGA-CZ-5465, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 76.2 years (27,838 days).
Specimen TCGA-CZ-5465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa7513a0-8219-43f4-a700-1c966c36fad9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5465-11A (Solid Tissue Normal), aliquot TCGA-CZ-5465-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e2ec92-4648-46c5-969c-b37802794067

The open-access MAF lists 108 somatic variants for this specimen: 94 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Frame Shift Del 14, Silent 11, Splice Region 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2, RNA 1, 5'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as rs1248399686, COSV54029658; called by muse, mutect2, varscan2
- ACTG1 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV59510482; called by muse, mutect2
- ADAM11 | c.1573C>G p.P525A | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52346369; called by muse, mutect2, varscan2
- ADGRL3 | c.2688G>A p.M896I (on ENST00000506720 / NM_001322402.2; = p.M828I on NM_015236.6) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV72230594; called by muse, mutect2, varscan2
- ANAPC1 | c.5177G>C p.R1726T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV61976060; called by muse, mutect2, varscan2
- ATXN2L | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57370465; called by muse, mutect2, varscan2
- BIRC6 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.571); catalogued as rs772972655, COSV70199343; called by muse, mutect2, varscan2
- BMS1 | c.3157G>C p.V1053L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV65733910; called by muse, mutect2, varscan2
- BRIP1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200960251, COSV51999752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C14orf39 | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58782036; called by mutect2, varscan2
- C5 | c.4762+1G>A p.X1588_splice | Splice Site (SNP) | VAF 62/160 reads (39%) | catalogued as COSV56327325; called by muse, mutect2, varscan2
- CATSPERE | c.858T>A p.S286R | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV63677999; called by muse, mutect2, varscan2
- CBLN1 | c.267A>T p.V89= | Splice Region (SNP) | VAF 7/178 reads (4%) | catalogued as COSV54654018; called by muse, mutect2
- CCDC183 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373655990; called by muse, mutect2, varscan2
- CCND2 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54223351; called by muse, mutect2, varscan2
- CCNJ | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs769713207, COSV56443009; called by muse, mutect2, varscan2
- CCPG1 | c.363A>C p.E121D | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); catalogued as COSV60525381; called by muse, mutect2, varscan2
- CD101 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV56718107; called by muse, varscan2
- CENPL | c.26C>G p.S9* | Nonsense Mutation (SNP) | VAF 31/149 reads (21%) | catalogued as COSV61892022; called by muse, mutect2, varscan2
- CFHR3 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.923); catalogued as COSV66402209; called by muse, mutect2, varscan2
- CLASP1 | c.1689A>G p.L563= | Splice Region (SNP) | VAF 83/203 reads (41%) | catalogued as COSV55324330; called by muse, mutect2, varscan2
- COASY | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1310804717, COSV55898884; called by muse, mutect2, varscan2
- CSF2RA | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV62624675; called by muse, mutect2, varscan2
- DNAH2 | c.11531G>C p.G3844A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV66719603; called by muse, mutect2, varscan2
- DRD3 | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55679726, COSV55680316; called by muse, mutect2, varscan2
- EFEMP2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs113167523, COSV57260154; called by muse, mutect2, varscan2
- EIF2AK2 | c.1131G>C p.W377C | Missense Mutation (SNP) | VAF 119/293 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51796420; called by muse, mutect2, varscan2
- ENPP3 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV62954235; called by muse, mutect2, varscan2
- ERBB4 | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53533250; called by muse, mutect2, varscan2
- FERMT1 | c.1181T>G p.F394C | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.316); catalogued as COSV54093255; called by muse, varscan2
- GAP43 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV59344338; called by muse, mutect2
- IL25 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59305934; called by muse, mutect2, varscan2
- KMT2A | c.11261A>G p.N3754S | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs564690648, COSV63285869; called by muse, mutect2, varscan2
- LETMD1 | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1192710073, COSV50397530; called by muse, mutect2, varscan2
- LRPPRC | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV53238379; called by muse, mutect2
- LRRK2 | c.3058C>A p.Q1020K | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); catalogued as COSV54153565; called by muse, mutect2, varscan2
- LTN1 | c.1391dup p.S465Kfs*13 | Frame Shift Ins (INS) | VAF 55/201 reads (27%) | catalogued as rs1348761327; called by mutect2, pindel, varscan2
- MYO15A | c.7816C>T p.R2606W | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1042742761, COSV52756817; called by muse, mutect2, varscan2
- NALCN | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485549287, COSV51921358; called by muse, mutect2, varscan2
- NRXN2 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 217/441 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55453415; called by muse, mutect2, varscan2
- OCIAD2 | c.388T>C p.C130R (on ENST00000508632 / NM_001014446.3; = p.T90= on NM_152398.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56716665; called by muse, mutect2, varscan2
- OPHN1 | c.1182C>G p.I394M | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62782464, COSV62783446, COSV62784904; called by muse, mutect2, varscan2
- OR2L8 | c.202del p.I68Lfs*3 | Frame Shift Del (DEL) | VAF 93/284 reads (33%) | catalogued as COSV61727479; called by mutect2, pindel, varscan2
- PARP14 | c.4548G>T p.K1516N | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV71734700; called by muse, mutect2, varscan2
- PBRM1 | c.478del p.E160Kfs*14 | Frame Shift Del (DEL) | VAF 121/235 reads (51%) | catalogued as COSV56294959, COSV56298403; called by mutect2, pindel, varscan2
- PCDH10 | c.2186T>G p.F729C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52094145; called by muse, mutect2, varscan2
- PDZD2 | c.7249T>G p.S2417A | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56858497; called by muse, mutect2, varscan2
- PITPNM1 | c.1487T>G p.L496R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62708255; called by muse, mutect2, varscan2
- PLD5 | c.803C>G p.A268G (on ENST00000442594; = p.A206G on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.489); catalogued as COSV100139729, COSV59146025, COSV59148712; called by muse, mutect2
- PORCN | c.1364T>G p.I455S (on ENST00000326194 / NM_203475.3; = p.I444S on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV52141736; called by muse, mutect2, varscan2
- PRICKLE1 | c.2132A>C p.K711T | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV58206990; called by muse, mutect2, varscan2
- PROS1 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as CS971880, CX973310, COSV62398453; called by muse, mutect2, varscan2
- PRRC2B | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV61937124; called by muse, mutect2, varscan2
- PTPRM | c.840A>T p.E280D | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59859451; called by muse, mutect2, varscan2
- PUM1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.638); catalogued as rs1468858539, COSV57085571; called by muse, mutect2, varscan2
- RANBP6 | c.2130A>C p.Q710H | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52389476; called by muse, mutect2, varscan2
- RGMA | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as COSV61234053; called by muse, mutect2, varscan2
- RHOJ | c.237+1G>C p.X79_splice | Splice Site (SNP) | VAF 39/153 reads (25%) | catalogued as COSV57458438; called by muse, mutect2, varscan2
- RMND1 | c.1203C>A p.V401= | Splice Region (SNP) | VAF 42/122 reads (34%) | catalogued as COSV60550611; called by muse, mutect2, varscan2
- S100A16 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV100905890; called by muse, varscan2
- SAMD9 | c.1287T>A p.D429E | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV66075242; called by muse, mutect2
- SEC14L5 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV52038500; called by muse, mutect2, varscan2
- SPATA17 | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs959371311, COSV65121971; called by muse, mutect2, varscan2
- TBC1D22B | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV65142790; called by mutect2, varscan2
- TIMMDC1 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV51786675; called by muse, mutect2, varscan2
- TMEM26 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.125); catalogued as COSV67492787; called by muse, mutect2, varscan2
- TMTC3 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57123945; called by muse, mutect2, varscan2
- TRIM11 | c.1159T>A p.Y387N | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV52857824; called by muse, mutect2, varscan2
- TTC3 | c.4405T>A p.S1469T | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV61290312, COSV61293224; called by muse, mutect2, varscan2
- TTN | c.28847C>T p.S9616L (on ENST00000591111; = p.S8689L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/168 reads (40%) | PolyPhen probably damaging (0.996); catalogued as rs764352461, COSV59947005; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2134A>C p.K712Q | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV54437569; called by muse, mutect2, varscan2
- USH2A | c.12330C>A p.Y4110* | Nonsense Mutation (SNP) | VAF 35/169 reads (21%) | catalogued as COSV56370448; called by muse, mutect2, varscan2
- USP24 | c.492T>A p.G164= | Splice Region (SNP) | VAF 64/192 reads (33%) | catalogued as COSV53767718; called by muse, mutect2, varscan2
- USP6NL | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV53211450; called by muse, varscan2
- VHL | c.473del p.L158Rfs*12 | Frame Shift Del (DEL) | VAF 66/111 reads (59%) | catalogued as CM164440, CM941379, COSV56543253, COSV56550270, COSV56558440, COSV56563690; called by mutect2, pindel, varscan2
- VPS35L | c.1546C>G p.H516D | Missense Mutation (SNP) | VAF 198/492 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51983179; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54295886; called by muse, mutect2, varscan2
- ZNF132 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 39/109 reads (36%) | catalogued as COSV54234984, COSV99571402; called by muse, mutect2, varscan2
- ZNF507 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV61331321; called by muse, mutect2, varscan2
- ABCA12 | c.1982del p.K661Sfs*3 (on ENST00000272895 / NM_173076.3; = p.K343Sfs*3 on NM_015657.3) | Frame Shift Del (DEL) | VAF 91/253 reads (36%) | called by mutect2, pindel, varscan2
- ALDOB | c.154_155insAA p.T52Kfs*27 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- AP3B2 | c.659del p.N220Tfs*9 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- BNC2 | c.2770del p.Q924Sfs*23 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- COL9A2 | c.490del p.Q164Rfs*19 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- DUOX2 | c.382_386del p.F128Qfs*171 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- ICE1 | c.4197_4201del p.T1400Dfs*11 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- KDM6A | c.466_468del p.V156del | In Frame Del (DEL) | VAF 111/284 reads (39%) | called by mutect2, pindel, varscan2
- MSMO1 | c.212del p.L71Yfs*8 | Frame Shift Del (DEL) | VAF 87/322 reads (27%) | called by mutect2, pindel, varscan2
- MUC2 | c.3914G>A p.W1305* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- PPP6R1 | c.1173_1176del p.H392Mfs*11 | Frame Shift Del (DEL) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- S100A16 | c.112_133del p.F38Sfs*2 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by pindel, varscan2
- SCRN1 | c.707dup p.A237Cfs*34 | Frame Shift Ins (INS) | VAF 70/172 reads (41%) | called by mutect2, pindel, varscan2
- SLC5A12 | c.1634del p.L545Yfs*80 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- TMTC3 | c.1670del p.S557Tfs*2 | Frame Shift Del (DEL) | VAF 44/160 reads (28%) | called by mutect2, pindel, varscan2
- BCL11A | c.12C>T p.R4= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs766153678, COSV59630149; called by muse, mutect2, varscan2
- FCGR3B | c.162G>A p.E54= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV54210010; called by muse, mutect2, varscan2
- FER1L6 | c.2586A>T p.T862= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV67549935; called by muse, mutect2, varscan2
- IGSF10 | c.5346A>T p.A1782= | Silent (SNP) | VAF 67/195 reads (34%) | catalogued as COSV56785334; called by muse, mutect2, varscan2
- IQUB | c.1311T>G p.L437= | Silent (SNP) | VAF 137/321 reads (43%) | catalogued as COSV61239356; called by muse, mutect2, varscan2
- MET | c.2817C>G p.V939= | Silent (SNP) | VAF 102/232 reads (44%) | catalogued as COSV59261476; called by muse, mutect2, varscan2
- MROH5 | c.3768A>G p.T1256= | Silent (SNP) | VAF 74/172 reads (43%) | catalogued as COSV61471700; called by muse, mutect2, varscan2
- PKHD1L1 | c.6000T>C p.N2000= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs1417303460, COSV65743057; called by muse, mutect2, varscan2
- SP1 | c.1101T>G p.A367= (on ENST00000327443 / NM_138473.3; = p.A360= on NM_003109.1) | Silent (SNP) | VAF 79/182 reads (43%) | catalogued as COSV59402906; called by muse, mutect2, varscan2
- TDGF1 | c.75G>A p.L25= | Silent (SNP) | VAF 15/337 reads (4%) | catalogued as COSV56126205; called by muse, mutect2
- TRMT2B | c.228A>G p.L76= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV58619587; called by muse, mutect2, varscan2
- FBXO24 | c.-1C>G | 5'UTR (SNP) | VAF 41/209 reads (20%) | catalogued as COSV99575451; called by muse, mutect2, varscan2
- NBEAP2 | n.951C>T | RNA (SNP) | VAF 80/236 reads (34%) | called by muse, mutect2, varscan2
- PDLIM2 | chr8:22594559 A>T | 3'Flank (SNP) | VAF 92/142 reads (65%) | catalogued as COSV56132820; called by muse, mutect2, varscan2
